Somatic mutation profile of tumor specimen ALCH-B208-TTP1-A (aliquot ALCH-B208-TTP1-A-1-0-D-A85H-36) from ALCHEMIST case ALCH-B208, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.5 years (25,367 days).
Specimen ALCH-B208-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 688a0569-0195-4987-848a-dfac1816a4a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B208-NB4-A (Blood Derived Normal), aliquot ALCH-B208-NB4-A-1-0-D-A85H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cefd004e-c7eb-4223-ab20-5d65f08b955a

The open-access MAF lists 109 somatic variants for this specimen: 83 protein-altering or splice-affecting, 19 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 19, Nonsense Mutation 3, 5'Flank 2, Intron 2, RNA 2, Frame Shift Del 1, In Frame Del 1, Splice Site 1, 5'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 162/821 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 192/495 reads (39%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALG1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as rs559805054, COSV52157393; called by muse, mutect2, varscan2
- ARHGEF12 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63104560; called by muse, mutect2, varscan2
- ARID1A | c.6358G>A p.E2120K | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61376361; called by muse, mutect2
- ATR | c.4814C>A p.P1605Q | Missense Mutation (SNP) | VAF 141/412 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV63384614; called by muse, mutect2, varscan2
- C11orf16 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371704323; called by muse, mutect2, varscan2
- C3orf70 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 60/578 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.458); catalogued as rs200872353; called by muse, mutect2
- CD5L | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 30/389 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63822521; called by muse, mutect2
- D2HGDH | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1354341670, COSV58323304; called by muse, mutect2, varscan2
- GALE | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52526005; called by muse, mutect2
- KCNG1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65368445; called by muse, mutect2
- KCNH3 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as rs770543962; called by muse, mutect2
- KRT83 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs767956481; called by muse, mutect2, varscan2
- LOXHD1 | c.1654+1G>A p.X552_splice | Splice Site (SNP) | VAF 24/83 reads (29%) | catalogued as rs1271511648; called by muse, mutect2, varscan2
- LRP1B | c.10480C>T p.R3494W | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs751868449, COSV67190947, COSV67194761; called by muse, mutect2, varscan2
- LRRIQ1 | c.4324G>A p.D1442N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV67829543; called by muse, mutect2
- MICAL3 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 57/374 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs377540344; called by muse, mutect2, varscan2
- MYO7B | c.2984G>A p.R995Q | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.359); catalogued as rs746926590; called by muse, mutect2
- NCOR1 | c.5167G>C p.E1723Q | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as COSV51980766; called by muse, mutect2
- NTAN1 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 52/518 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.173); catalogued as rs1181481101, COSV55075185; called by muse, mutect2
- OR7A17 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.406); catalogued as rs1460459771, COSV59414271; called by muse, mutect2
- PAPPA | c.4185C>G p.F1395L | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.995); catalogued as rs1458891213, COSV60282705; called by muse, mutect2
- PCDH17 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 24/353 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as COSV64976236; called by muse, mutect2
- PIEZO1 | c.2734G>A p.D912N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1263547711; called by muse, mutect2, varscan2
- PKD2L2 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 25/496 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99296557; called by muse, mutect2
- PKHD1 | c.11609C>T p.S3870L | Missense Mutation (SNP) | VAF 98/660 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs138360112; called by muse, mutect2, varscan2
- PRKD2 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99354355; called by muse, mutect2
- PRPH | c.1328T>C p.I443T | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs1285284536, COSV57679386; called by muse, mutect2, varscan2
- RPL31 | c.140A>G p.K47R | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as rs1418315642; called by muse, mutect2
- SBF2 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 19/608 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as rs1372841015; called by muse, mutect2
- SLC25A13 | c.1051C>A p.L351I | Missense Mutation (SNP) | VAF 146/775 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs746502556; called by muse, mutect2, varscan2
- SLCO4A1 | c.1812-4G>A | Splice Region (SNP) | VAF 61/307 reads (20%) | catalogued as rs766651885; called by muse, mutect2, varscan2
- SNAP91 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV99535638; called by muse, mutect2, varscan2
- SPOCD1 | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202136039; called by muse, mutect2
- ST6GAL2 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 78/387 reads (20%) | PolyPhen probably damaging (0.985); catalogued as rs1032769723, COSV62416723; called by muse, mutect2, varscan2
- AFF2 | c.2282G>A p.S761N | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2
- AFG1L | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ARHGAP32 | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- AUTS2 | c.573T>G p.S191R | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); called by muse, mutect2
- BCR | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 22/132 reads (17%) | called by muse, varscan2
- C1orf158 | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 32/655 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.281); called by muse, mutect2
- CDC5L | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 62/427 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CKAP5 | c.3763G>A p.D1255N | Missense Mutation (SNP) | VAF 44/379 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- DLGAP3 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 57/796 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- DOCK10 | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 110/314 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ERBIN | c.2660T>G p.L887R | Missense Mutation (SNP) | VAF 104/588 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GFRA1 | c.171G>C p.E57D | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- HTT | c.5660G>A p.G1887E | Missense Mutation (SNP) | VAF 50/394 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- IMPDH1 | c.436A>T p.T146S (on ENST00000470772 / NM_001142573.2; = p.T232S on NM_000883.4) | Missense Mutation (SNP) | VAF 42/549 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.034); called by muse, mutect2
- INTS8 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2
- KCNH2 | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2
- MAK | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 40/651 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2
- NCOR1 | c.6282G>T p.R2094S | Missense Mutation (SNP) | VAF 104/987 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NCOR1 | c.5899G>T p.E1967* | Nonsense Mutation (SNP) | VAF 19/262 reads (7%) | called by muse, mutect2
- NCOR1 | c.5312G>C p.R1771T | Missense Mutation (SNP) | VAF 40/400 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NCOR1 | c.4833G>C p.Q1611H | Missense Mutation (SNP) | VAF 80/718 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDHB4 | c.1841T>A p.F614Y | Missense Mutation (SNP) | VAF 34/561 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHB4 | c.1842C>G p.F614L | Missense Mutation (SNP) | VAF 32/568 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- PLA2G7 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.06); called by muse, mutect2
- PNN | c.1091_1111del p.V364_T370del | In Frame Del (DEL) | VAF 40/306 reads (13%) | called by mutect2, pindel
- PRKAR2B | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- RAB43 | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RELN | c.5381G>A p.C1794Y | Missense Mutation (SNP) | VAF 274/1161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RYR3 | c.10057A>C p.K3353Q (on ENST00000389232; = p.K3354Q on NM_001036.6) | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); called by muse, mutect2
- SCARF1 | c.611A>C p.D204A | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SCG3 | c.1393T>A p.Y465N | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- SLC35D1 | c.360A>C p.Q120H | Missense Mutation (SNP) | VAF 124/699 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC39A13 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SNAP91 | c.1061C>G p.P354R | Missense Mutation (SNP) | VAF 29/666 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- STK26 | c.1202A>T p.K401M | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.401); called by muse, mutect2
- TARS2 | c.368A>T p.D123V | Missense Mutation (SNP) | VAF 30/645 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- TMED6 | c.173A>C p.Q58P | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TTC39A | c.1597del p.A533Pfs*12 (on ENST00000447632 / NM_001297665.1; = p.A498Pfs*12 on NM_001080494.3) | Frame Shift Del (DEL) | VAF 24/139 reads (17%) | called by mutect2, pindel*, varscan2
- TTLL8 | c.984C>G p.C328W | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP36 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.55); called by mutect2, varscan2
- ZBED6 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.022); called by muse, mutect2
- ZCCHC18 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2
- ZNF142 | c.2213G>A p.G738D (on ENST00000411696 / NM_001379660.1; = p.G538D on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.057); called by muse, mutect2
- ZNF334 | c.1665G>T p.R555S | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- ZNF420 | c.745A>G p.K249E | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZNF653 | c.1666dup p.L556Pfs*139 | Frame Shift Ins (INS) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- ZNF99 | c.2555A>T p.K852M | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- ABTB2 | c.1149C>T p.A383= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.2082C>T p.P694= | Silent (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- CDK11B | c.1617G>A p.V539= | Silent (SNP) | VAF 10/167 reads (6%) | called by muse, mutect2
- CKAP2 | c.330C>G p.T110= (on ENST00000378037 / NM_001098525.2; = p.T109= on NM_018204.5) | Silent (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- GPRIN1 | c.492T>A p.T164= | Silent (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- GRAMD1B | c.1977C>T p.L659= | Silent (SNP) | VAF 25/465 reads (5%) | catalogued as COSV59205348; called by muse, mutect2
- INTS2 | c.147G>A p.L49= | Silent (SNP) | VAF 28/245 reads (11%) | called by muse, mutect2, varscan2
- LRRTM4 | c.93G>A p.Q31= | Silent (SNP) | VAF 15/358 reads (4%) | called by muse, mutect2
- MPZL2 | c.423C>T p.S141= | Silent (SNP) | VAF 49/245 reads (20%) | catalogued as rs370925743; called by muse, mutect2, varscan2
- NPAT | c.4128T>C p.D1376= | Silent (SNP) | VAF 28/490 reads (6%) | called by muse, mutect2
- OR10G7 | c.435C>T p.T145= | Silent (SNP) | VAF 22/346 reads (6%) | catalogued as rs756653254, COSV100389782; called by muse, mutect2
- OR2H1 | c.333C>A p.I111= | Silent (SNP) | VAF 49/373 reads (13%) | called by muse, mutect2, varscan2
- OR5T1 | c.615C>T p.H205= | Silent (SNP) | VAF 58/257 reads (23%) | catalogued as rs112370265; called by muse, mutect2, varscan2
- OTOGL | c.951C>A p.I317= (on ENST00000547103; = p.I308= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- PKP1 | c.1509C>T p.N503= | Silent (SNP) | VAF 44/255 reads (17%) | catalogued as rs146580475; called by muse, mutect2, varscan2
- TGIF2 | c.483T>C p.G161= | Silent (SNP) | VAF 39/304 reads (13%) | called by muse, mutect2, varscan2
- TIAM1 | c.3438C>T p.C1146= | Silent (SNP) | VAF 51/299 reads (17%) | catalogued as rs141775592; called by muse, mutect2, varscan2
- ZFHX3 | c.888G>C p.S296= | Silent (SNP) | VAF 43/184 reads (23%) | called by muse, mutect2, varscan2
- ZNF454 | c.210A>G p.E70= | Silent (SNP) | VAF 49/233 reads (21%) | called by muse, mutect2, varscan2
- AC064807.1 | n.1157T>C | RNA (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- ADAMTS10 | c.-21A>C | 5'UTR (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- C2orf74 | chr2:61157906 G>A | 5'Flank (SNP) | VAF 47/243 reads (19%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4427G>A | Intron (SNP) | VAF 82/308 reads (27%) | catalogued as rs782640328, COSV100251696; called by mutect2, varscan2
- RPL22L1 | c.103-57C>G | Intron (SNP) | VAF 74/153 reads (48%) | called by muse, mutect2, varscan2
- SNORA60 | n.59G>A | RNA (SNP) | VAF 46/450 reads (10%) | called by muse, mutect2
- ZFP36L1 | chr14:68796227 C>T | 5'Flank (SNP) | VAF 36/238 reads (15%) | called by muse, mutect2, varscan2
